Somatic mutation profile of tumor specimen MMRF_2566_1_BM_CD138pos (aliquot MMRF_2566_1_BM_CD138pos_T1_KHS5U_K15180) from MMRF case MMRF_2566, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 57.2 years (20,910 days).
Specimen MMRF_2566_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ece3c000-5b61-4baa-9d65-1d32ed9870e8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2566_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2566_1_PB_Whole_C2_KHS5U_K15179; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d981515e-5c71-4c60-9e25-5da7306b9fd5

The open-access MAF lists 116 somatic variants for this specimen: 49 protein-altering or splice-affecting, 8 silent, 59 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, 3'UTR 30, Intron 12, Silent 8, 5'UTR 8, 5'Flank 4, RNA 3, Nonsense Mutation 2, Frame Shift Ins 2, 3'Flank 2, Splice Site 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL6A2 | c.2627G>A p.R876H | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1012567148, CM1312460, COSV52431403; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- PCDH15 | c.3441dup p.F1148Ifs*8 | Frame Shift Ins (INS) | VAF 35/68 reads (51%) | catalogued as rs770832663; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- ACTG1 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 91/204 reads (45%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.988); catalogued as rs375159565; called by muse, mutect2, varscan2
- BCO2 | c.1343C>G p.S448C | Missense Mutation (SNP) | VAF 57/129 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as rs150993927; called by muse, mutect2, varscan2
- CD4 | c.498dup p.K167Efs*13 | Frame Shift Ins (INS) | VAF 18/46 reads (39%) | catalogued as rs781937995; called by mutect2, varscan2
- CSMD3 | c.9395C>A p.T3132K (on ENST00000297405 / NM_001363185.1; = p.T2963K on NM_052900.3) | Missense Mutation (SNP) | VAF 68/142 reads (48%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.606); catalogued as COSV52292760, COSV99847328; called by muse, mutect2, varscan2
- DNAH10 | c.5332C>T p.R1778W (on ENST00000409039; = p.R1717W on NM_207437.3) | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs533314912; called by muse, mutect2, varscan2
- EGR1 | c.71C>T p.P24L | Missense Mutation (SNP) | VAF 206/374 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.142); catalogued as rs547507736, COSV53518778; called by muse, varscan2
- ERICH6 | c.1631G>A p.R544H | Missense Mutation (SNP) | VAF 31/174 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs138919004; called by muse, mutect2, varscan2
- IGLV3-1 | c.227T>C p.I76T | Missense Mutation (SNP) | VAF 55/114 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.749); catalogued as rs573464772; called by muse, varscan2
- IRX6 | c.182G>A p.R61Q | Missense Mutation (SNP) | VAF 40/74 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs773356371; called by muse, mutect2, varscan2
- KCNH4 | c.847C>T p.R283C | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1004264752, COSV52918380; called by muse, mutect2, varscan2
- KLF6 | c.62A>G p.Y21C | Missense Mutation (SNP) | VAF 49/86 reads (57%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.903); catalogued as rs780547330; called by muse, mutect2, varscan2
- KLK4 | c.476-7G>A | Splice Region (SNP) | VAF 43/146 reads (29%) | catalogued as rs377181928, COSV100133621; called by muse, mutect2, varscan2
- KRTAP10-3 | c.22G>A p.V8I | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs781944871, COSV59975624; called by muse, mutect2
- KSR2 | c.1394-2G>A p.X465_splice | Splice Site (SNP) | VAF 30/76 reads (39%) | catalogued as rs1158034251; called by muse, mutect2, varscan2
- MEGF9 | c.1021G>A p.D341N | Missense Mutation (SNP) | VAF 45/187 reads (24%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as COSV64237987; called by muse, mutect2, varscan2
- NAA11 | c.446G>T p.R149L | Missense Mutation (SNP) | VAF 9/154 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.024); catalogued as rs913797875; called by muse, mutect2
- NOS3 | c.701G>A p.R234H | Missense Mutation (SNP) | VAF 102/149 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs758294669; called by muse, mutect2, varscan2
- PDZRN3 | c.2179C>T p.R727C | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as rs970562680, COSV99729240; called by muse, mutect2, varscan2
- PKP1 | c.1501G>T p.A501S | Missense Mutation (SNP) | VAF 54/196 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.142); catalogued as rs201459638; called by muse, mutect2, varscan2
- SIM1 | c.559G>A p.G187S | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1317491192; called by muse, mutect2, varscan2
- SYNE1 | c.16603A>T p.M5535L (on ENST00000367255 / NM_182961.4; = p.M5464L on NM_033071.3) | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs1283757623; called by muse, mutect2, varscan2
- TERT | c.220G>A p.V74M | Missense Mutation (SNP) | VAF 61/141 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); catalogued as rs771343717; called by muse, mutect2, varscan2
- TRIM8 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.535); catalogued as COSV100193035; called by muse, mutect2, varscan2
- TTN | c.28363G>A p.V9455M (on ENST00000591111; = p.V8528M on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/113 reads (25%) | PolyPhen probably damaging (0.983); catalogued as rs563073635; ClinVar: likely benign; called by muse, mutect2, varscan2
- ALMS1 | c.2894A>G p.Y965C | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.222); called by muse, mutect2
- ANKRD27 | c.233A>G p.N78S | Missense Mutation (SNP) | VAF 171/359 reads (48%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- AP005242.2 | n.849+1G>T | Splice Site (SNP) | VAF 15/39 reads (38%) | called by muse, mutect2, varscan2
- ARHGEF2 | c.1070C>G p.A357G (on ENST00000361247 / NM_001162383.2; = p.A329G on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ERBIN | c.383C>T p.S128F | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EXOC4 | c.1297A>T p.K433* | Nonsense Mutation (SNP) | VAF 68/207 reads (33%) | called by muse, mutect2, varscan2
- EXOC4 | c.1298A>T p.K433I | Missense Mutation (SNP) | VAF 68/207 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- FDPS | c.1235G>A p.R412H | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2
- FLII | c.1132A>T p.M378L | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- FRMPD2 | c.1191C>A p.D397E | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.874); called by muse, varscan2
- GPR135 | c.370G>A p.V124M | Missense Mutation (SNP) | VAF 55/125 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRRTM3 | c.499A>T p.N167Y | Missense Mutation (SNP) | VAF 35/147 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MROH2B | c.3100G>T p.V1034F | Missense Mutation (SNP) | VAF 78/163 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- PCDHA12 | c.1514C>T p.S505L | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PPHLN1 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 45/95 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- PRAME | c.383C>T p.S128F | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- SEBOX | c.337C>T p.P113S | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.55); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SYNE1 | c.5201T>C p.M1734T (on ENST00000367255 / NM_182961.4; = p.M1741T on NM_033071.3) | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- TNRC6A | c.1766G>A p.G589E | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TRPV5 | c.484T>A p.F162I | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.192); called by muse, mutect2
- YBX1 | c.623A>C p.Y208S | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF37A | c.1350C>G p.Y450* | Nonsense Mutation (SNP) | VAF 9/60 reads (15%) | called by muse, mutect2
- ZNF561 | c.1249G>C p.G417R | Missense Mutation (SNP) | VAF 52/431 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- GPR132 | c.771G>A p.P257= | Silent (SNP) | VAF 35/124 reads (28%) | catalogued as rs763198085, COSV100317476; called by muse, mutect2, varscan2
- KPNA6 | c.1569C>T p.I523= | Silent (SNP) | VAF 37/78 reads (47%) | catalogued as rs376876446; called by muse, mutect2, varscan2
- LRRC38 | c.126C>T p.C42= | Silent (SNP) | VAF 3/36 reads (8%) | catalogued as rs1407904496; called by muse, mutect2
- RYR3 | c.4935C>T p.D1645= | Silent (SNP) | VAF 41/125 reads (33%) | catalogued as rs755738535, COSV66781535; called by muse, mutect2, varscan2
- SIGLEC10 | c.1092C>T p.N364= | Silent (SNP) | VAF 57/139 reads (41%) | catalogued as rs555512085, COSV59481167, COSV99042997; called by muse, mutect2, varscan2
- SLC16A11 | c.444C>T p.A148= (on ENST00000308009; = p.A124= on NM_153357.3) | Silent (SNP) | VAF 15/37 reads (41%) | called by muse, mutect2, varscan2
- SPATA31E1 | c.3321C>T p.D1107= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as COSV57790744; called by muse, mutect2, varscan2
- TCERG1L | c.1341C>T p.L447= | Silent (SNP) | VAF 19/130 reads (15%) | catalogued as rs1266818473; called by muse, mutect2, varscan2
- ABCA9 | c.2282-54A>G | Intron (SNP) | VAF 5/9 reads (56%) | called by muse, mutect2, varscan2
- ABCF2 | c.*340G>A | 3'UTR (SNP) | VAF 45/145 reads (31%) | catalogued as rs1195332654; called by muse, mutect2, varscan2
- ACTB | c.-27-99T>C | Intron (SNP) | VAF 89/152 reads (59%) | called by muse, mutect2, varscan2
- AK4 | c.*5114G>T | 3'UTR (SNP) | VAF 27/49 reads (55%) | called by muse, mutect2, varscan2
- AMN | c.296-54C>T | Intron (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- AP2A1 | c.1785+48C>T | Intron (SNP) | VAF 27/72 reads (38%) | catalogued as rs1003034965; called by muse, mutect2, varscan2
- BCL7A | chr12:122021521 C>G | 5'Flank (SNP) | VAF 65/137 reads (47%) | catalogued as COSV55849440; called by muse, mutect2, varscan2
- BCL9L | c.-61C>T | 5'UTR (SNP) | VAF 74/192 reads (39%) | catalogued as COSV58311306; called by muse, mutect2, varscan2
- C1orf158 | c.*1449T>G | 3'UTR (SNP) | VAF 63/152 reads (41%) | catalogued as rs1409490325; called by muse, mutect2, varscan2
- C5orf64 | n.513-44528G>A | Intron (SNP) | VAF 51/384 reads (13%) | called by muse, mutect2, varscan2
- CACNB4 | c.*3712A>G | 3'UTR (SNP) | VAF 17/44 reads (39%) | called by muse, mutect2, varscan2
- CAMK2N1 | c.*1027T>C | 3'UTR (SNP) | VAF 18/52 reads (35%) | catalogued as rs1023516297; called by muse, mutect2, varscan2
- CBX5 | c.*6846G>A | 3'UTR (SNP) | VAF 18/49 reads (37%) | called by muse, mutect2, varscan2
- CCNJ | c.*1861T>C | 3'UTR (SNP) | VAF 12/13 reads (92%) | called by muse, mutect2, varscan2
- CCNYL2 | n.1398G>A | RNA (SNP) | VAF 36/163 reads (22%) | catalogued as rs1159298224; called by muse, mutect2, varscan2
- CDCA8 | c.*237C>T | 3'UTR (SNP) | VAF 22/42 reads (52%) | called by muse, mutect2, varscan2
- CLEC1A | c.*1337_*1339del | 3'UTR (DEL) | VAF 15/30 reads (50%) | called by mutect2, pindel, varscan2
- CLK1 | c.-93T>C | 5'UTR (SNP) | VAF 17/31 reads (55%) | called by muse, mutect2, varscan2
- DMBT1 | c.*150G>A | 3'UTR (SNP) | VAF 30/102 reads (29%) | catalogued as rs955785206; called by muse, mutect2, varscan2
- DNAJC27 | c.*3240T>A | 3'UTR (SNP) | VAF 12/24 reads (50%) | catalogued as rs983769590; called by muse, mutect2, varscan2
- DTX1 | c.-264C>A | 5'UTR (SNP) | VAF 36/84 reads (43%) | called by muse, mutect2, varscan2
- DTX1 | c.-125T>C | 5'UTR (SNP) | VAF 36/80 reads (45%) | catalogued as rs1235044107; called by muse, mutect2, varscan2
- DTX1 | c.-8T>C | 5'UTR (SNP) | VAF 10/30 reads (33%) | called by muse, varscan2
- EIF1B | c.*316G>A | 3'UTR (SNP) | VAF 3/45 reads (7%) | catalogued as rs954506761; called by muse, mutect2
- ETV5 | c.*224A>G | 3'UTR (SNP) | VAF 5/147 reads (3%) | called by muse, mutect2
- FAT3 | c.*750G>A | 3'UTR (SNP) | VAF 43/72 reads (60%) | called by muse, mutect2, varscan2
- FBXO32 | c.*5160C>T | 3'UTR (SNP) | VAF 17/36 reads (47%) | called by muse, mutect2, varscan2
- GNAI1 | c.-143C>A | 5'UTR (SNP) | VAF 54/137 reads (39%) | called by muse, mutect2, varscan2
- GSDMB | c.*130T>C | 3'UTR (SNP) | VAF 20/50 reads (40%) | called by muse, mutect2, varscan2
- GUCY1B2 | n.1329C>T | RNA (SNP) | VAF 4/88 reads (5%) | called by muse, mutect2
- HMGA2 | c.282+4900A>C | Intron (SNP) | VAF 22/52 reads (42%) | called by muse, mutect2, varscan2
- ITCH | chr20:34509586 G>C | 3'Flank (SNP) | VAF 16/43 reads (37%) | called by muse, mutect2, varscan2
- IYD | chr6:150368975 G>C | 5'Flank (SNP) | VAF 59/231 reads (26%) | catalogued as rs1479217391; called by muse, mutect2, varscan2
- KCNJ2 | c.-58T>C | 5'UTR (SNP) | VAF 10/20 reads (50%) | called by muse, mutect2
- LIFR | c.*6479T>G | 3'UTR (SNP) | VAF 13/88 reads (15%) | called by muse, mutect2, varscan2
- LINC02873 | n.1656A>G | RNA (SNP) | VAF 65/115 reads (57%) | catalogued as rs1478112667; called by muse, mutect2, varscan2
- LTB | c.162+56C>T | Intron (SNP) | VAF 47/81 reads (58%) | called by muse, mutect2, varscan2
- METTL6 | c.531+245T>C | Intron (SNP) | VAF 46/142 reads (32%) | called by muse, mutect2, varscan2
- MGAM | c.4618+13496C>T | Intron (SNP) | VAF 67/300 reads (22%) | catalogued as rs758327344; called by muse, mutect2, varscan2
- MLF1 | c.*475G>A | 3'UTR (SNP) | VAF 34/54 reads (63%) | called by muse, mutect2
- MLF1 | c.*477T>C | 3'UTR (SNP) | VAF 36/56 reads (64%) | called by muse, mutect2
- MOB2 | chr11:1469916 C>T | 3'Flank (SNP) | VAF 74/170 reads (44%) | called by muse, mutect2, varscan2
- MVD | c.403+199C>T | Intron (SNP) | VAF 24/55 reads (44%) | catalogued as rs1216153914; called by muse, mutect2, varscan2
- NTM | c.-225C>T | 5'UTR (SNP) | VAF 83/223 reads (37%) | called by muse, mutect2, varscan2
- OSBP2 | chr22:30694202 G>T | 5'Flank (SNP) | VAF 18/410 reads (4%) | called by muse, mutect2
- PARPBP | c.*1196C>A | 3'UTR (SNP) | VAF 14/17 reads (82%) | catalogued as rs749862428; called by muse, mutect2, varscan2
- PCDH15 | c.*3324A>C | 3'UTR (SNP) | VAF 41/54 reads (76%) | called by muse, mutect2, varscan2
- PKP2 | c.*720A>T | 3'UTR (SNP) | VAF 7/30 reads (23%) | called by muse, mutect2, varscan2
- PKP2 | c.*428T>C | 3'UTR (SNP) | VAF 39/89 reads (44%) | called by muse, mutect2, varscan2
- PRSS40A | n.318-802G>A | Intron (SNP) | VAF 36/154 reads (23%) | called by muse, mutect2, varscan2
- RBM4 | c.412+1058T>C | Intron (SNP) | VAF 14/27 reads (52%) | called by muse, mutect2, varscan2
- RORA | c.*3917T>C | 3'UTR (SNP) | VAF 66/93 reads (71%) | called by muse, mutect2, varscan2
- RXRG | chr1:165445194 C>T | 5'Flank (SNP) | VAF 40/90 reads (44%) | called by muse, varscan2
- SERTAD4 | c.*1502T>C | 3'UTR (SNP) | VAF 8/17 reads (47%) | called by muse, mutect2, varscan2
- SLC6A6 | c.*2307G>A | 3'UTR (SNP) | VAF 62/170 reads (36%) | catalogued as rs772551260, COSV99817312; called by muse, mutect2, varscan2
- THUMPD3 | c.*1295G>T | 3'UTR (SNP) | VAF 11/57 reads (19%) | called by muse, mutect2, varscan2
- TNKS | c.*3897T>C | 3'UTR (SNP) | VAF 20/48 reads (42%) | called by muse, mutect2, varscan2
- WDR41 | c.*1738A>G | 3'UTR (SNP) | VAF 42/85 reads (49%) | catalogued as rs939482298; called by muse, mutect2, varscan2
- ZNF605 | c.*2420C>T | 3'UTR (SNP) | VAF 20/40 reads (50%) | called by muse, mutect2, varscan2
